Gene-level copy-number profile of tumor specimen ALCH-B3J7-TTP1-A from ALCHEMIST case ALCH-B3J7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,686 days).
Specimen ALCH-B3J7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f18fb81-caef-44cb-a271-8be9a5dea898.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3J7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,265 have no estimate.
https://portal.gdc.cancer.gov/files/4b03c5e7-4f6b-43fe-b993-9acaff84423e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 241; copy number 1: 8,673; copy number 2: 48,676; copy number 3: 505; copy number 4: 155; copy number 5: 35; copy number 6: 15; copy number 7: 1; copy number 8: 2; copy number 9: 48; copy number 12: 5; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 241 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,474,973–13,514,003, 1 gene (within-gene range 0–1): LRRC38.
- chr1:143,736,066–143,739,506, 1 gene: AC239800.2.
- chr1:143,811,359–143,846,504, 2 genes: AC239798.1, AC239798.2.
- chr1:143,905,487–143,934,776, 2 genes (within-gene range 0–2): AC246680.1, RPL22P5.
- chr2:25,369,136–25,375,845, 1 gene: ARNILA.
- chr2:89,872,463–89,916,052, 6 genes: IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33.
- chr2:90,121,786–91,781,169, 25 genes: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr2:232,349,754–232,368,697, 2 genes: ECEL1P3, AC068134.3.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr11:32,435,738–32,440,383, 6 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr12:116,368,764–116,389,471, 1 gene: AC079384.1.
- chr14:18,333,726–19,830,253, 75 genes (broad region; genes not listed).
- chr16:46,469,341–46,931,289, 18 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr17:142,789–431,062, 9 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97.
- chr17:959,034–959,366, 1 gene (within-gene range 0–1): AC036164.1.
- chr17:9,244,666–9,244,897, 1 gene: AC005695.3.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–1): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:46,909,742–46,911,512, 1 gene: LINC01974.
- chr19:24,033,401–24,163,425, 6 genes: AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:50,840,615–50,840,749, 1 gene (within-gene range 0–2): TMSB4XP6.
- chr20:56,577,563–56,688,695, 5 genes: LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P.
- chr21:8,603,547–13,120,807, 48 genes: RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:43,039,516–43,089,419, 1 gene (within-gene range 0–1): TTLL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 108 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 6: AC239800.3, LINC02591, RNU1-143P.
- chr5:58,198–2,967,955, 83 genes, copy number 5–12 (broad region; genes not listed).
- chr5:44,698,431–44,828,592, 6 genes, copy number 5: AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr5:173,888,349–173,961,980, 1 gene, copy number 5: CPEB4.
- chr8:132,775,358–132,848,807, 3 genes, copy number 5: PHF20L1, AF230666.2, AF230666.1.
- chr9:136,612,024–136,617,181, 1 gene, copy number 5: LINC01451.
- chr10:132,181,225–132,185,962, 1 gene, copy number 6 (within-gene range 1–6): AL512622.1.
- chr17:59,707,192–59,847,544, 4 genes, copy number 6 (within-gene range 4–6): VMP1, AC040904.1, MIR21, RNU6-450P.
- chr20:64,290,187–64,313,132, 2 genes, copy number 8: CICP4, LINC00266-1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 7: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 15: LINC00313, AP001048.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 1–5): GATD3A.

Autosomal genes at a single copy (total copy number 1): 8,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
